Somatic mutation profile of tumor specimen TCGA-25-1320-01A (aliquot TCGA-25-1320-01A-01W-0492-08) from TCGA case TCGA-25-1320, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 65.8 years (24,018 days).
Specimen TCGA-25-1320-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ef1a0c0-5702-499a-8b13-be32f626300b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-25-1320-10A (Blood Derived Normal), aliquot TCGA-25-1320-10A-01W-0492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60cd0ee9-33b2-47c9-90af-8520d7bbcebd

The open-access MAF lists 83 somatic variants for this specimen: 63 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 17, Nonsense Mutation 5, Frame Shift Del 4, Splice Site 1, 5'UTR 1, In Frame Ins 1, Splice Region 1, Frame Shift Ins 1, 5'Flank 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A2ML1 | c.4033C>T p.R1345* | Nonsense Mutation (SNP) | VAF 57/407 reads (14%) | catalogued as rs374267852; called by muse, mutect2, varscan2
- ADAMTS20 | c.3317A>T p.E1106V | Missense Mutation (SNP) | VAF 108/328 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV67126327; called by muse, mutect2, varscan2
- ARHGEF11 | c.4321-1G>A p.X1441_splice | Splice Site (SNP) | VAF 17/199 reads (9%) | catalogued as COSV100168846; called by muse, mutect2
- BNC1 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61756516; called by muse, varscan2
- BPIFA1 | c.509A>G p.Q170R | Missense Mutation (SNP) | VAF 160/2896 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.631); catalogued as rs1239644182, COSV100845656; called by muse, mutect2
- C3 | c.3871G>A p.E1291K | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV55569621, COSV55575561; called by muse, mutect2
- C3 | c.393C>A p.F131L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99837101; called by muse, mutect2, varscan2
- CCHCR1 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs774674896, COSV66183625; called by muse, mutect2
- CNTN3 | c.2234T>A p.V745D | Missense Mutation (SNP) | VAF 79/984 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV99725664; called by muse, mutect2
- COL12A1 | c.8827C>A p.P2943T | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59412424; called by muse, mutect2
- CYP7B1 | c.970C>A p.R324S | Missense Mutation (SNP) | VAF 75/309 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as rs773055558, COSV59582633; called by muse, mutect2, varscan2
- DNAH3 | c.6472G>A p.E2158K | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760584539, COSV54532648; called by muse, mutect2
- DNAH5 | c.13285C>T p.R4429* | Nonsense Mutation (SNP) | VAF 56/1198 reads (5%) | catalogued as COSV54229483; called by muse, mutect2
- DSG2 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 23/299 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as rs749602291, COSV55197247; ClinVar: uncertain significance; called by muse, mutect2
- EEF2K | c.1738C>T p.H580Y | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV53778709; called by muse, varscan2
- ELAVL2 | c.79T>A p.S27T | Missense Mutation (SNP) | VAF 221/2195 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV99806858; called by muse, mutect2, varscan2
- EVX2 | c.145C>A p.L49I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.609); catalogued as COSV100420793; called by muse, mutect2, varscan2
- FBXL18 | c.1612C>T p.L538F | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66107436; called by muse, mutect2, varscan2
- GIGYF2 | c.1405G>T p.V469F | Missense Mutation (SNP) | VAF 134/1528 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV65246616; called by muse, mutect2
- HUWE1 | c.11093G>A p.R3698Q | Missense Mutation (SNP) | VAF 50/1300 reads (4%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.885); catalogued as COSV99473633; called by muse, mutect2
- IP6K3 | c.81dup p.H28Afs*8 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | catalogued as rs1404845875; called by pindel, varscan2
- IRF6 | c.440A>G p.E147G | Missense Mutation (SNP) | VAF 87/460 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV65418691; called by muse, mutect2, varscan2
- LRRK2 | c.1749A>C p.E583D | Missense Mutation (SNP) | VAF 90/964 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as COSV54144302; called by muse, mutect2
- MET | c.798G>C p.R266S | Missense Mutation (SNP) | VAF 37/409 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.287); catalogued as COSV59257054; called by muse, mutect2
- MYH15 | c.3092G>A p.S1031N | Missense Mutation (SNP) | VAF 32/1071 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV99843993; called by muse, mutect2
- NAGLU | c.721G>T p.V241L | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as CM023646, COSV99864311; called by muse, mutect2
- NCAN | c.2612C>T p.T871M | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs145824706; called by muse, mutect2, varscan2
- NOL4 | c.65C>A p.S22* | Nonsense Mutation (SNP) | VAF 18/367 reads (5%) | catalogued as COSV99307867, COSV99308211; called by muse, mutect2
- PIGZ | c.1282G>A p.G428S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs539732732, COSV53013068; called by muse, mutect2, varscan2
- PLCB2 | c.1104G>T p.E368D | Missense Mutation (SNP) | VAF 8/246 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV99542443; called by muse, mutect2
- PLCH1 | c.1549G>T p.A517S (on ENST00000340059 / NM_001130960.2; = p.A529S on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/214 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as COSV58200325; called by muse, mutect2
- PPP1R15A | c.1453C>T p.R485* | Nonsense Mutation (SNP) | VAF 66/619 reads (11%) | catalogued as rs756641166, COSV99566190; called by muse, mutect2, varscan2
- PPP1R3A | c.3287T>C p.I1096T | Missense Mutation (SNP) | VAF 130/633 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.417); catalogued as rs771586895, COSV52876470; called by muse, mutect2, varscan2
- PRDM16 | c.2725G>C p.E909Q | Missense Mutation (SNP) | VAF 12/189 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99578169; called by muse, mutect2
- RAB11FIP4 | c.690C>A p.S230R | Missense Mutation (SNP) | VAF 11/237 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV100365649; called by muse, mutect2
- RARS2 | c.425T>G p.V142G | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV65759947; called by muse, mutect2, varscan2
- RHBG | c.545C>A p.S182Y | Missense Mutation (SNP) | VAF 75/427 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV54801749; called by muse, mutect2, varscan2
- RPUSD3 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs781682741, COSV100047763; called by muse, mutect2, varscan2
- RUFY1 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 36/393 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as COSV100106359; called by muse, mutect2
- SAG | c.243G>C p.L81F | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101300697; called by muse, mutect2, varscan2
- SHLD2 | c.1924C>T p.P642S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.217); catalogued as rs1396072878, COSV100079417; called by mutect2, varscan2
- SNX27 | c.1118A>G p.N373S | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs149636067; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SP100 | c.1290G>A p.K430= | Splice Region (SNP) | VAF 46/438 reads (11%) | catalogued as rs780962221, COSV50974599, COSV50990521; called by muse, mutect2, varscan2
- STC2 | c.890A>T p.Y297F | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV54178335; called by muse, mutect2, varscan2
- SULF1 | c.1916G>A p.W639* | Nonsense Mutation (SNP) | VAF 28/542 reads (5%) | catalogued as rs1191542873, COSV52684726, COSV52690781; called by muse, mutect2
- TEK | c.476G>A p.G159D | Missense Mutation (SNP) | VAF 149/1903 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.618); catalogued as rs1315371549, COSV101193516; called by muse, mutect2
- TLL2 | c.1514C>G p.T505S | Missense Mutation (SNP) | VAF 252/446 reads (57%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV100780397, COSV63575118; called by mutect2, varscan2
- TP53 | c.372del p.C124* | Frame Shift Del (DEL) | VAF 170/310 reads (55%) | catalogued as CM1210346, COSV52731101, COSV52944837; called by mutect2, pindel, varscan2
- TRPC4 | c.2533T>A p.F845I (on ENST00000379705 / NM_016179.4; = p.F850I on NM_003306.3) | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.236); catalogued as COSV100157549, COSV59000027; called by muse, mutect2, varscan2
- TRPC4 | c.2024C>T p.T675I | Missense Mutation (SNP) | VAF 45/355 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV58990800; called by muse, mutect2, varscan2
- TSC2 | c.3087G>T p.M1029I | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV54756255, COSV99554076; called by muse, mutect2, varscan2
- TTI1 | c.437C>G p.S146C | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV65060498; called by muse, mutect2, varscan2
- YWHAG | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 252/1038 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56899794; called by muse, mutect2, varscan2
- ZNF420 | c.1734G>C p.Q578H | Missense Mutation (SNP) | VAF 17/227 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.878); catalogued as COSV100421445; called by muse, mutect2
- ZNF536 | c.2011C>T p.R671W | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1180623012, COSV62818669; called by muse, mutect2, varscan2
- DTNB | c.326_328dup p.S109_L110insR | In Frame Ins (INS) | VAF 113/466 reads (24%) | called by mutect2, pindel, varscan2
- ERCC2 | c.656A>C p.D219A | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by mutect2, varscan2
- KIR2DL4 | c.772G>C p.G258R (on ENST00000396284; = p.G219R on NM_001080770.2) | Missense Mutation (SNP) | VAF 308/2049 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRFIP1 | c.1346_1347del p.T449Sfs*4 (on ENST00000392000 / NM_001137552.2; = p.T425Sfs*4 on NM_004735.4) | Frame Shift Del (DEL) | VAF 34/248 reads (14%) | called by pindel, varscan2
- NCAPG2 | c.3011_3014del p.H1004Rfs*7 | Frame Shift Del (DEL) | VAF 19/64 reads (30%) | called by mutect2, pindel, varscan2
- SEPHS2 | c.484_486del p.L162del | In Frame Del (DEL) | VAF 33/260 reads (13%) | called by mutect2, pindel, varscan2
- TAF1L | c.4480del p.D1494Ifs*14 | Frame Shift Del (DEL) | VAF 204/1331 reads (15%) | called by mutect2, pindel, varscan2
- TPTE | c.1636G>T p.V546F (on ENST00000618007 / NM_199261.4; = p.V528F on NM_199259.4) | Missense Mutation (SNP) | VAF 82/788 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.426); called by muse, varscan2
- ACRBP | c.111T>G p.P37= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV57523077; called by muse, mutect2, varscan2
- ADAMTS16 | c.1959C>T p.A653= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as rs759807523, COSV56978522, COSV56993777; called by muse, mutect2, varscan2
- BAZ1B | c.2397A>G p.K799= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs1199134787, COSV59988658; called by mutect2, varscan2
- CHRDL2 | c.1143C>T p.I381= (on ENST00000376332 / NM_001304415.1; = p.Q400* on NM_015424.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 15/306 reads (5%) | catalogued as COSV99734019; called by muse, mutect2
- EEF2K | c.1659C>T p.F553= | Silent (SNP) | VAF 26/160 reads (16%) | catalogued as COSV53778695; called by muse, varscan2
- FLG2 | c.4374A>T p.G1458= | Silent (SNP) | VAF 56/2256 reads (2%) | catalogued as rs1456975751, COSV101166084, COSV66172276; called by muse, mutect2
- GNAI3 | c.150G>A p.V50= | Silent (SNP) | VAF 95/825 reads (12%) | catalogued as COSV63983268; called by muse, varscan2
- KIF21B | c.1119G>A p.K373= | Silent (SNP) | VAF 14/204 reads (7%) | catalogued as COSV100144941, COSV59754490; called by muse, mutect2
- MRPS25 | c.228G>A p.L76= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV99507802; called by muse, mutect2, varscan2
- NOL9 | c.1341G>A p.P447= | Silent (SNP) | VAF 194/838 reads (23%) | catalogued as rs568168221, COSV100891507; called by muse, mutect2, varscan2
- NPAP1 | c.522C>T p.D174= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs368120585, COSV100274980; called by muse, mutect2, varscan2
- PCYT1A | c.66C>T p.N22= | Silent (SNP) | VAF 117/763 reads (15%) | catalogued as rs201702214, COSV53056000; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLCH1 | c.1548G>T p.R516= (on ENST00000340059 / NM_001130960.2; = p.R528= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/212 reads (4%) | catalogued as COSV100397909; called by muse, mutect2
- PPP1R10 | c.1059C>T p.G353= | Silent (SNP) | VAF 237/1147 reads (21%) | catalogued as COSV64738465; called by muse, mutect2, varscan2
- RDH8 | c.750C>T p.S250= (on ENST00000651512; = p.S230= on NM_015725.4) | Silent (SNP) | VAF 93/431 reads (22%) | catalogued as rs757511859, COSV50673924, COSV50673929; called by muse, mutect2, varscan2
- VAV3 | c.672A>G p.R224= | Silent (SNP) | VAF 101/627 reads (16%) | catalogued as COSV58377210; called by muse, varscan2
- ZFP28 | c.2517G>A p.S839= | Silent (SNP) | VAF 87/1648 reads (5%) | catalogued as rs202181134; called by muse, mutect2
- DNAH8 | chr6:38723029 C>A | 5'Flank (SNP) | VAF 113/1171 reads (10%) | catalogued as COSV100546679; called by muse, mutect2, varscan2
- NMB | c.*56G>A | 3'UTR (SNP) | VAF 17/89 reads (19%) | catalogued as COSV64685364; called by muse, mutect2, varscan2
- OR10K1 | c.-1C>T | 5'UTR (SNP) | VAF 109/242 reads (45%) | catalogued as COSV99193829, COSV99194096; called by muse, mutect2, varscan2
